Somatic mutation profile of tumor specimen TCGA-S9-A7IY-01A (aliquot TCGA-S9-A7IY-01A-11D-A34A-08) from TCGA case TCGA-S9-A7IY, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 39.5 years (14,422 days).
Specimen TCGA-S9-A7IY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8661d5c-a0c6-48a9-b984-90b354da3872.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7IY-10A (Blood Derived Normal), aliquot TCGA-S9-A7IY-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbca662f-5967-4da8-bc56-c787c589e879

The open-access MAF lists 25 somatic variants for this specimen: 23 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 17, Silent 2, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 37/99 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATP4B | c.17A>T p.E6V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100089637; called by muse, mutect2, varscan2
- CBY1 | c.35A>G p.K12R | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV99319864; called by muse, mutect2, varscan2
- CCDC180 | c.3149C>A p.A1050D | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100826595; called by muse, mutect2, varscan2
- CCND1 | c.772A>G p.S258G | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV99919272; called by muse, mutect2, varscan2
- CDC34 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs375521090; called by muse, mutect2
- CIC | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99359081; called by muse, mutect2, varscan2
- DNAH7 | c.10958G>A p.R3653H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781510286, COSV56781690; called by muse, mutect2, varscan2
- DNMBP | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.117); catalogued as COSV100143196; called by muse, mutect2, varscan2
- ENPP1 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762558218, COSV62936693; called by muse, mutect2, varscan2
- EPB41L3 | c.2101G>A p.G701R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338064574, COSV100548265; called by muse, mutect2, varscan2
- IFIH1 | c.2698C>A p.P900T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99718450; called by muse, mutect2, varscan2
- ING5 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100545923; called by muse, mutect2, varscan2
- KIR2DL1 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1399848185; called by muse, mutect2
- MFSD10 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1274818009, COSV99296075; called by muse, mutect2, varscan2
- PRMT8 | c.1034A>G p.Y345C | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV54217777, COSV99713218; called by muse, mutect2, varscan2
- QARS1 | c.365T>C p.I122T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs778805533, COSV100069796; called by muse, mutect2, varscan2
- SYNE1 | c.9601A>G p.N3201D (on ENST00000367255 / NM_182961.4; = p.N3208D on NM_033071.3) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.122); catalogued as COSV99555555; called by muse, mutect2, varscan2
- CIC | c.1008del p.C336Wfs*33 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- CNOT1 | c.2724dup p.E909Rfs*14 | Frame Shift Ins (INS) | VAF 29/160 reads (18%) | called by mutect2, pindel, varscan2
- FUBP1 | c.843dup p.I282Hfs*23 | Frame Shift Ins (INS) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- GIGYF2 | c.3622C>T p.Q1208* | Nonsense Mutation (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2
- PIK3R1 | c.1723_1724del p.K575Dfs*26 (on ENST00000521381 / NM_181523.3; = p.K305Dfs*26 on NM_181504.4) | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- ADORA2B | c.534C>G p.P178= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100419975; called by muse, mutect2, varscan2
- KIAA0319L | c.693T>C p.S231= | Silent (SNP) | VAF 39/58 reads (67%) | catalogued as COSV100356963; called by muse, mutect2, varscan2
